Surgical pathology report (de-identified scan), TCGA case TCGA-28-1749, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-1749-01A (Primary Tumor).

[page 1 of 5]
Department of Pathology & Laboratory
Medicine

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A, G. BRAIN, LEFT FRONTAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

B. BRAIN, LEFT FRONTAL, EXCISIONAL BIOPSY, NCI#1:

- Glioblastoma multiforme
- 0% of tumor necrosis
- Over 90% of tumor cellularity

C. BRAIN, LEFT FRONTAL, EXCISIONAL BIOPSY, NCI#2:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 90% of tumor cellularity

D. BRAIN, LEFT FRONTAL, EXCISIONAL BIOPSY, NCI#3:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 70% of tumor cellularity

E. BRAIN, LEFT FRONTAL, EXCISIONAL BIOPSY, NCI#4:

- Glioblastoma multiforme, WHO grade IV
- 3% of tumor necrosis
- 90% of tumor cellularity

F. BRAIN, LEFT FRONTAL, EXCISIONAL BIOPSY, NCI#5:

- Glioblastoma multiforme, WHO grade IV
- 3% of tumor necrosis
- 90% of tumor cellularity

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar. Hence, the low 5% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors.

Patient Case(s):

[page 2 of 5]
***** Addendum - Please See End of Report *****

PATIENT:

PATH #:

[REDACTED]. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas. [REDACTED] between laminin-8 and glial tumor grade, recurrence, and patient survival. [REDACTED] Accordingly, elevated expression of $\beta 1$ and $\beta 2$ in this tumor suggest the tumor aggressiveness intermediate between the $\beta 1 \downarrow$ (or normal)/ $\beta 2$ normal (or $\uparrow$) (the most favorable prognosis) and $\beta 1 \uparrow$ / $\beta 2 \downarrow$ (least favorable prognosis).

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas [REDACTED] Molecular subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) has been shown to be associated with a relative resistance of glioblastoma multiforme to radiation therapy.

[REDACTED] Prognostic Associations of Activated Mitogen-Activated Protein Kinase and Akt Pathways in Glioblastoma. [REDACTED]

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case predicts a relative resistance to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

IDC2a: Selected slides were reviewed in consultation with

HISTORY:

MICROSCOPIC:

Sections disclose necrotizing malignant neoplasm featuring hyperchromatic elongate enlarged nuclei with numerous mitotic figures, associated with florid microvascular proliferation.

SPECIAL STUDIES:

IMMUNOSTAINS:

MGMT (G1): 5%

PTEN (G1): Loss (1+)

pMAPK (G1): 20% of tumor nuclei are positive and 60% of tumor cell cytoplasm positive

Laminin beta-1 (8/411) (G1): Upregulated (3+ in endothelial cells)

Laminin beta-2 (9/421) (G1): Upregulated (2-3+ in endothelial cells)

EGFR amplification by FISH is pending

GROSS:

A. LEFT FRONTAL TUMOR

Labeled with the patient's name, labeled "left frontal tumor", and received fresh for intraoperative consultation and subsequently submitted in formalin is a 0.6 x 0.5 x 0.3 cm portion of soft gray tissue with pinpoint area of tumor.

Entirely submitted.

A1. Frozen remnant - 1

A2. Remaining tissue - 1

[page 3 of 5]
***** Addendum - Please See End of Report *****

PATIENT:

PATH #:

B. LEFT FRONTAL NCI#1

Labeled with the patient's name, labeled "left frontal NCI", and received in formalin are two portions of soft pale tan tissue ranging from 0.4 to 0.5 cm in greatest dimension and measuring 0.9 x 0.4 x 0.2 cm in aggregate. Entirely submitted.

B1. 2

C. LEFT FRONTAL NCI#2

Labeled with the patient's name, labeled "left frontal NCI", and received in formalin are two portions of soft pale tan tissue measuring 0.6 and 0.7 cm in greatest dimension amounting in aggregate to 1.1 x 0.6 x 0.2 cm. Entirely submitted.

C1. 2

D. LEFT FRONTAL NCI#3

Labeled with the patient's name, labeled "left frontal NCI", and received in formalin are two portions of soft pale tan tissue measuring 0.5 and 0.9 cm in greatest dimension amounting in aggregate to 1.3 x 0.4 x 0.2 cm. Entirely submitted.

D1. 2

E. LEFT FRONTAL NCI#4

Labeled with the patient's name, labeled "left frontal NCI", and received in formalin are two pieces of soft pale tan tissue with areas of hemorrhage measuring 0.4 and 0.7 cm in greatest dimension and amounting in aggregate to 3.3 x 0.6 x 0.2 cm. Entirely submitted.

E1. 2

F. LEFT FRONTAL NCI#5

Labeled with the patient's name, labeled "left frontal NCI", and received in formalin is a 1.1 x 0.8 x 0.3 cm portion of soft pale tan tissue with areas of hemorrhage. Entirely submitted.

F1. 1

G. LEFT FRONTAL PERMANENT

Labeled with the patient's name, labeled "left frontal permanent", and received in formalin are three portions of pale tan-pink hemorrhagic tissue ranging from 0.3 to 1.7 cm in greatest dimension and amounting in aggregate to 2.2 x 1.1 x 0.3 cm. Entirely submitted.

G1. 3

Gross dictated by

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

A. LEFT FRONTAL FS + TP:

High-grade glioma

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by the Department of Pathology and Laboratory Medicine. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Electronically signed

[page 4 of 5]
***** Addendum - Please See End of Report *****

PATIENT:

PATH #:

***ADDENDUM

FISH (FLUORESCENCE IN SITU HYBRIDIZATION) for EGFR

RESULTS:

Number of cells analyzed: 40

Ratio of EGFR/CEP: 15.3

Percentage of cells with ≥ 4 copies of EGFR: 0

Amplification: YES

High Level of Polysomy: NO

INTERPRETATION:

1. Samples are interpreted as Positive if :
- a. EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells.
- b. For lung only, when high level of polysomy ($\geq$ four copies of EGFR in $\geq 40\%$ of cells) is present.
2. Samples are interpreted as Negative if EGFR to CEP 7 signal ratio is < 2.0 or for lung only, in the absence of high level of polysomy ($\geq$ four copies of EGFR).
3. Samples are considered inconclusive, requiring consult with the pathologist, when EGFR to CEP 7 signal ratio is ≥ 2.0 in $< 10\%$ of analyzed cells or for lung only, when high level of polysomy ($\geq$ four copies of EGFR) is present in $< 40\%$ of cells. These cases also need to be co-read.

REFERENCES

[page 5 of 5]
***** Addendum - Please See End of Report *****

PATIENT: ■

PATH #: ■

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

1. Electronically signed ■

2. Electronically signed ■

Source: NCI Genomic Data Commons file 09dabde6-93e8-44b9-8c30-542971d15423 (TCGA-28-1749.52397AE2-9FBE-452A-AD46-714FACF92043.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).